Gene-level copy-number profile of tumor specimen TCGA-GS-A9TT-01A from TCGA case TCGA-GS-A9TT, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 70.6 years (25,794 days).
Specimen TCGA-GS-A9TT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.c7823372-b451-4159-9cb8-d4de8479bda8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GS-A9TT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7b6dd5c3-4f70-4bfe-ab40-fac817a1e95b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,670; copy number 2: 49,897; copy number 3: 6,226; copy number 4: 22; copy number 5: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GS-A9TT-01A-11D-A381-01): tumor purity 0.91, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:89,588,049–89,712,590, 2 genes, copy number 5 (within-gene range 3–5): ATP2B1, ATP2B1-AS1.
- chr12:89,726,936–89,754,152, 3 genes, copy number 5: RNA5SP365, MRPL2P1, RNU6-148P.

Autosomal genes at a single copy (total copy number 1): 1,291. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
